Somatic mutation profile of tumor specimen TCGA-KN-8427-01A (aliquot TCGA-KN-8427-01A-11D-2310-10) from TCGA case TCGA-KN-8427, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 54.4 years (19,854 days).
Specimen TCGA-KN-8427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3965c5a-4503-47b2-897f-4c2d7f9898ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8427-11A (Solid Tissue Normal), aliquot TCGA-KN-8427-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd8d9f78-08e3-448b-aa67-ac4863286310

The open-access MAF lists 76 somatic variants for this specimen: 50 protein-altering or splice-affecting, 21 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 21, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 2, 3'UTR 2, 5'UTR 1, 5'Flank 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11B1 | c.595+1G>A p.X199_splice | Splice Site (SNP) | VAF 37/125 reads (30%) | catalogued as rs1264073726, COSV99455794; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 45/79 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AKR1C1 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 184/931 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV101080584; called by muse, mutect2, varscan2
- ANKRD7 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.183); catalogued as COSV54555057, COSV54556102; called by muse, mutect2, varscan2
- ARL4C | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV60213480; called by muse, mutect2, varscan2
- COPA | c.1443G>C p.R481= | Splice Region (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99616944; called by muse, mutect2, varscan2
- CPLX2 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770667199, COSV64000190; called by muse, mutect2, varscan2
- CRNN | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 29/318 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV55123266; called by muse, mutect2
- CYP2C9 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | catalogued as rs749575375; called by muse, mutect2
- CYP4F11 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200410691; called by muse, mutect2, varscan2
- DDRGK1 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1300270790; called by muse, mutect2, varscan2
- DIDO1 | c.2899G>T p.D967Y | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99827315; called by muse, mutect2
- DSG2 | c.2207C>T p.T736I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55197369; called by muse, mutect2, varscan2
- F13B | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV66373764; called by muse, mutect2, varscan2
- FGFBP2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs765344183, COSV52587825; called by muse, mutect2, varscan2
- GPR101 | c.1208T>C p.I403T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99981706; called by muse, mutect2, varscan2
- GPR161 | c.549C>A p.H183Q | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV54793508; called by muse, mutect2, varscan2
- GPR87 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV99608969; called by muse, mutect2
- LATS2 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 77/138 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66879567; called by muse, mutect2, varscan2
- LIN28B | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as COSV100559130; called by muse, mutect2
- MARCHF1 | c.539C>G p.T180R (on ENST00000274056; = p.T163R on NM_017923.4) | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1250065471, COSV56821776; called by muse, mutect2, varscan2
- MBD5 | c.3632A>C p.K1211T | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.034); catalogued as rs751272971; called by muse, mutect2, varscan2
- NAF1 | c.789G>T p.E263D | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV56806061; called by muse, mutect2
- SPTA1 | c.5829G>A p.W1943* | Nonsense Mutation (SNP) | VAF 34/97 reads (35%) | catalogued as COSV63753904; called by muse, mutect2, varscan2
- SYT6 | c.668A>C p.K223T (on ENST00000610222 / NM_001366225.1; = p.K138T on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV65774473; called by muse, mutect2, varscan2
- TYW1B | c.1793T>C p.I598T | Missense Mutation (SNP) | VAF 98/593 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs782588999; called by muse, varscan2
- COL1A1 | c.2601C>G p.S867R | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- DCLRE1C | c.1289G>C p.R430T (on ENST00000378278 / NM_001350965.2; = p.R315T on NM_022487.4) | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX50 | c.1906G>C p.V636L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ESPL1 | c.1796C>G p.T599S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAL3ST3 | c.151T>G p.C51G | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- GAL3ST3 | c.150C>A p.S50R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.243); called by muse, mutect2
- GRM7 | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ITGA3 | c.1997C>G p.S666C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- JCAD | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 41/203 reads (20%) | called by muse, mutect2, varscan2
- KIF19 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- KYNU | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by mutect2, varscan2
- LEF1 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MCTP1 | c.2801T>G p.I934S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- MS4A5 | c.197T>G p.V66G | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- NOM1 | c.1329_1334delinsA p.A444Gfs*9 | Frame Shift Del (DEL) | VAF 34/88 reads (39%) | called by pindel, varscan2*
- NTM | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- OBSCN | c.3565G>C p.E1189Q | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SETD1B | c.1264_1279del p.A422Sfs*81 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel
- SSC4D | c.1369G>C p.G457R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TIMM17A | c.335T>C p.M112T | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- TTLL12 | c.1644G>A p.Q548= | Splice Region (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.68849T>C p.F22950S (on ENST00000591111; = p.F15526S on NM_003319.4) | Missense Mutation (SNP) | VAF 32/216 reads (15%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC13A | c.2126A>C p.K709T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ZNF563 | c.106_116del p.T36Pfs*14 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- ABCA6 | c.3168T>G p.A1056= | Silent (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- AGBL1 | c.1632C>A p.T544= | Silent (SNP) | VAF 43/80 reads (54%) | called by muse, mutect2, varscan2
- ANKRD27 | c.1722C>A p.R574= | Silent (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2, varscan2
- C9orf72 | c.879G>A p.L293= | Silent (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- CSMD2 | c.1869T>C p.I623= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99596137; called by muse, mutect2, varscan2
- CSMD3 | c.1164T>C p.H388= | Silent (SNP) | VAF 26/296 reads (9%) | catalogued as COSV99834054; called by muse, mutect2
- FMO3 | c.174C>T p.V58= | Silent (SNP) | VAF 37/172 reads (22%) | called by muse, mutect2, varscan2
- MMP12 | c.966T>G p.S322= | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as COSV100405093; called by muse, mutect2, varscan2
- PAPPA2 | c.4038A>C p.S1346= | Silent (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.11718T>C p.T3906= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as rs754032046; called by muse, mutect2, varscan2
- PRDX2 | c.78A>G p.K26= | Silent (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- RFX6 | c.2262G>T p.P754= | Silent (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2, varscan2
- ROR2 | c.1437G>C p.L479= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100996150; called by muse, mutect2, varscan2
- RTKN2 | c.1521T>G p.P507= | Silent (SNP) | VAF 18/209 reads (9%) | called by muse, mutect2
- SEMA3A | c.2298G>A p.R766= | Silent (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- SP2 | c.1149C>G p.T383= | Silent (SNP) | VAF 38/85 reads (45%) | called by muse, varscan2
- TMUB2 | c.888C>T p.F296= (on ENST00000538716 / NM_001353177.2; = p.F276= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 66/165 reads (40%) | called by muse, mutect2, varscan2
- TTN | c.3714T>G p.T1238= (on ENST00000591111; = p.T1192= on NM_003319.4) | Silent (SNP) | VAF 28/340 reads (8%) | catalogued as COSV59950710, COSV60107421, COSV60194267; called by muse, mutect2
- WDR35 | c.6C>T p.F2= | Silent (SNP) | VAF 40/122 reads (33%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.999C>T p.I333= | Silent (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- ZNF667 | c.1659A>G p.K553= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV99410221; called by muse, mutect2, varscan2
- CKLF | chr16:66566137 del G | 3'Flank (DEL) | VAF 20/37 reads (54%) | catalogued as COSV50451709; called by mutect2, pindel, varscan2
- DCAF13 | chr8:103415344 T>A | 5'Flank (SNP) | VAF 6/64 reads (9%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2
- FZD7 | c.*1356T>G | 3'UTR (SNP) | VAF 106/229 reads (46%) | catalogued as COSV99637494; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.-32C>T | 5'UTR (SNP) | VAF 7/47 reads (15%) | catalogued as rs1165617326, COSV100523027; called by muse, mutect2, varscan2
- SPRY3 | c.*7232G>A | 3'UTR (SNP) | VAF 23/132 reads (17%) | catalogued as COSV100249607; called by muse, mutect2, varscan2
